Gene-level copy-number profile of tumor specimen ALCH-ABE2-TTP1-A from ALCHEMIST case ALCH-ABE2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.9 years (20,790 days).
Specimen ALCH-ABE2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c243e565-9552-4554-8fac-bc5cc8d78f73.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABE2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/7d327e76-c8f3-44ab-b5a8-bd50543c2b48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 66; copy number 2: 56,501; copy number 3: 1,722; copy number 4: 49; copy number 5: 4; copy number 6: 6; copy number 7: 4; copy number 8: 3; copy number 10: 1; copy number 11: 2; copy number 18: 2; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,616,811–103,668,268, 3 genes: AMY2A, AMY1A, AC105272.1.
- chr15:22,178,107–22,185,402, 2 genes: IGHV1OR15-3, IGHV4OR15-8.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 6 (within-gene range 2–6): TTC34, AC242022.2, AC242022.1.
- chr15:21,298,233–21,325,241, 2 genes, copy number 18 (within-gene range 1–18): AC068446.2, RNU6-1235P.
- chr15:21,951,242–21,951,323, 1 gene, copy number 7: MIR5701-3.
- chr15:22,145,939–22,160,868, 3 genes, copy number 6: AC010760.1, RPS8P10, IGHV1OR15-1.
- chr16:32,262,827–32,380,049, 5 genes, copy number 5–19: AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3.
- chr21:8,680,538–8,680,934, 1 gene, copy number 7: CR381572.2.
- chr21:43,107,942–43,168,646, 1 gene, copy number 11 (within-gene range 2–11): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 11: AP001631.1.
- chr22:18,846,811–18,861,049, 2 genes, copy number 7: AC008132.1, BCRP7.
- chr22:18,906,028–18,947,732, 3 genes, copy number 8 (within-gene range 2–8): DGCR6, AC007326.4, PRODH.
- chr22:21,370,064–21,371,945, 1 gene, copy number 10: AP000552.1.
- chr22:23,926,900–23,929,574, 1 gene, copy number 5: AP000350.2.

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
